Gene-level copy-number profile of tumor specimen ALCH-ADI0-TTP1-A from ALCHEMIST case ALCH-ADI0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.4 years (27,543 days).
Specimen ALCH-ADI0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc24a00e-e16b-4d62-a3fb-86997aa5e3cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADI0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/042bf1de-1e9e-4407-a67c-354f6d95ac87

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,797; copy number 2: 47,230; copy number 3: 6,370; copy number 4: 2; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:47,331,406–47,352,702, 1 gene: MYBPC3.
- chr16:88,468,918–88,469,031, 1 gene (within-gene range 0–2): MIR5189.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,664,633–105,669,843, 1 gene, copy number 20 (within-gene range 2–20): IGHGP.

Autosomal genes at a single copy (total copy number 1): 4,797. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
